Somatic mutation profile of tumor specimen 0DUB87 from CCDI case PBCKIF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Metastatic signet ring cell carcinoma; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 8.8 years (3,229 days).
Specimen 0DUB87: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adbd7f9e-f614-4a63-8cf5-0e829ff59f15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB68 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4486c57-a7db-4b27-b2a1-163a904986c6

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 2, 5'UTR 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943419160, COSV100802623, COSV64198810; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 34/819 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs1420189684, COSV56181614; called by muse, mutect2
- HCN1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 67/745 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100300372, COSV57538426; called by muse, mutect2
- IGSF1 | c.3521A>C p.K1174T | Missense Mutation (SNP) | VAF 35/601 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV100811778, COSV100811883, COSV63839442; called by muse, mutect2
- PCDH17 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 50/275 reads (18%) | catalogued as COSV64972577; called by muse, mutect2, varscan2
- RNF34 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 101/667 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs782385808; called by muse, mutect2, varscan2
- URB2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 48/714 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760578029; called by muse, mutect2
- WDPCP | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 60/594 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs753480088, COSV55414635; called by muse, mutect2, varscan2
- FAM32A | c.256A>C p.K86Q | Missense Mutation (SNP) | VAF 48/648 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- KLHL38 | c.1636T>G p.Y546D | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT75 | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 81/720 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, varscan2
- LAMB2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 30/750 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2
- PGBD4 | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 105/698 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RPS21 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); called by muse, mutect2
- RSPO3 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF432 | c.1194G>C p.E398D | Missense Mutation (SNP) | VAF 21/599 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ASB8 | c.9C>G p.S3= | Silent (SNP) | VAF 92/657 reads (14%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 23/232 reads (10%) | called by muse, varscan2
- ZNF783 | c.802+3275A>G | Intron (SNP) | VAF 43/455 reads (9%) | called by muse, mutect2
